Surgical pathology report (de-identified scan), TCGA case TCGA-KB-A93H, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University Health Network, Toronto, specimen TCGA-KB-A93H-01A (Primary Tumor).

[page 1 of 5]
DEPARTMENT OF PATHOLOGY

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	F	Reported:	
Ordering MD:	[REDACTED]		
Copy To:	[REDACTED]		
Service:	[REDACTED]		
Visit #:	[REDACTED]		
Location:	[REDACTED]		
Facility:	[REDACTED]		

Specimen(s) Received

1. Stom-Resection: proximal stomach and distal esophagus with quick section on esophageal margin and gastric margin
2. Surgical Waste
3. Esophagus: Final esophageal margin
4. Esophagus: Final most proximal esophageal margin

Diagnosis

1. Gastroesophagectomy specimen:
- well differentiated adenocarcinoma of the proximal stomach extending into the distal esophagus
- invading into adventitial/serosal adipose tissue, (mpT3)
- hyperplastic polyp with focal intramucosal adenocarcinoma, (mpT1a)
- one out of 23 lymph nodes positive for metastatic adenocarcinoma (1/23), (pN1)
- resection margin negative for carcinoma

See synoptic report

2. Surgical waste:
- no tissue submitted for histological examination - see comment
3. Final esophageal margin:
- negative for carcinoma
4. Final most proximal esophageal margin:
- negative for carcinoma

acc 100-0-3
path Adenocarcinoma, tubular 8211/3
Adenocarcinoma, intestinal
type 8144/3
Site Gastric body 016.2
81041E/14

Comment

2. "This specimen has been examined by gross visual examination only. No microscopic examination has been performed. If there is a clinical indication or suspicion of an abnormality that would require additional studies then the signing pathologist (below) should be contacted within one month of the issuing of this report."

Synoptic Data

Specimen:	Portion of stomach, gastric body
	Distal esophagus
Procedure:	Partial gastrectomy, proximal
Tumor Site:	Body, posterior wall
	Body, lesser curvature

[page 2 of 5]
Surgical Pathology Consultation Report

Histologic Type:	Other: distal esophagus
Histologic Grade:	Adenocarcinoma, intestinal type
Tumor Size:	G1: Well differentiated
	Greatest dimension: 6.4 cm
	Additional dimension: 6.3 cm
	Additional dimension: 2.0 cm
Microscopic Extent of Tumor:	Tumor invades subserosal connective tissue
Proximal Margin:	Uninvolved by invasive carcinoma
	Carcinoma in situ/adenoma not identified at proximal margin
Distal Margin:	Uninvolved by invasive carcinoma
	Carcinoma in situ/adenoma not identified at distal margin
Omental (Radial) Margins:	Uninvolved by invasive carcinoma
Deep Margin:	Not applicable
	Distance of invasive carcinoma from closest margin: 0.1 mm
	Closest margin: Deep margin
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Not identified: not identified
Perineural Invasion:	Not identified: not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT3: Tumor invades subserosal connective tissue, without involvement of visceral peritoneum or adjacent structures
Regional Lymph Nodes (pN):	pN1: Metastasis in 1 to 2 perigastric lymph nodes
	Number of lymph nodes examined: 23
	Number of lymph nodes involved: 1
Distant Metastasis (pM):	Not applicable: N/A
Additional Pathologic Findings:	Intestinal metaplasia
	Dysplasia
	Other gastritis: chronic atrophic gastritis
	Polyp(s): hyperplastic polyp with intramucosal adenocarcinoma

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

The specimen container is labeled with the patient's name and as "Proximal stomach + distal esophagus quick section on esophageal margin + gastric margin QS".

RESECTION SPECIMEN: Partial Gastrosophagectomy, serosal surface and area of tumor painted with silver nitrate

FIXATION: Received fresh, placed in formalin

DIMENSIONS:

Length along lesser curvature 8.3 cm

Length along greater curvature 15.0 cm

Circumference of distal gastric margin 16.5 cm

Length of tubular esophagus 1.6-cm

Width of tubular esophagus 3.6-cm

TUMOR:

LOCATION:

- Gastric region: GEJ

[page 3 of 5]
- Lesser curvature
- Predominantly posterior wall
- For GEJ tumors: 80% in stomach

- CONFIGURATION: Exophytic with an ulcerated center, non-circumferential

- DIMENSIONS: Diameters 6.4 x 6.3 cm
Depth 2.0 cm

- DESCRIPTIVE CHARACTERISTICS: The exposed surface is congested and necrotic. The cut surface has a pink-tan friable appearance

- PERFORATION: No

- DISTANCE FROM MARGINS:

- PROXIMAL 0.6 cm
- DISTAL 2.5 cm
- RADIAL 0.2 cm (adventitial surface of esophagus) (in the area of the stomach the tumor is covered by adipose tissue)

ESTIMATED DEPTH OF INVASION: Into perigastric fat and at least one adjacent lymph node

LESIONS IN NONCANCEROUS STOMACH: There is a villiform polyp that is present 2.5 cm from the distal edge of the tumor approaching the distal margin (grossly difficult to visualize after frozen section). The polyp measures 2.7 x 1.5 x 0.7 cm.

LYMPH NODES: Multiple perigastric lymph nodes are identified along the lesser curvature ranging in maximum dimension from 0.3 to 2.9 cm. Several of these grossly appear to be involved by tumor.

FROZEN SECTION:

- 1A closest stomach margin
- 1B closest esophageal margin
- 1C remainder of the esophageal margin
- 1D random stomach remote from tumor, margin painted with India ink
- 1E tumor

Multiple pieces of tissue are stored frozen

Photographs are taken of the specimen

Representative Sections:

- 1A-1E frozen section tissue, resubmitted
- 1F uninvolved GE junction
- 1G-1H longitudinal sections of proximal end of tumor with adventitial/non-peritonealized surface
- 1I-1K deepest aspect of tumor, transverse slices proximal to distal
- 1L-1M tumor with closest adjacent involved lymph node
- 1N-1O longitudinal sections of distal end of tumor with adjacent stomach
- 1P stomach, fundus
- 1Q stomach, body
- 1R-1S polyp, in toto
- 1T-1W remainder of gastric margin, en face
- 1X-1Z multiple lymph nodes, the block
- 1AA 1 lymph node, bisected
- 1AB 1 lymph node, bisected
- 1AC-1AD 1 lymph node, bisected

2. The specimen container is labeled with the patient's name and as "Surgical waste". The specimen consists of 2 pieces of small bowel. The smaller piece is stapled closed at one end. It measures 1.9 cm in length with a luminal

[page 4 of 5]
Surgical Pathology Consultation Report

diameter of 3.5 cm. The serosa and mucosa are unremarkable. The longer piece is stapled closed at each end. It measures 7.0 cm in length with a luminal circumference of 4.2 cm. There are small fragments of adherent adipose tissue. The serosa and mucosa are grossly unremarkable. No sections are taken.

3. The specimen container is labeled with the patient's name and as "Final esophageal margin". The specimen consists of a portion of mostly muscularis that is infiltrated with staples. The tissue measures 5.2 cm in length by 0.2 cm across.

3A representative soft tissue

4. The specimen container is labeled with the patient's name and as "final most proximal esophageal margin". The specimen consists of a ring shaped piece of mucosa measuring 2.5 x 1.7 x 0.2 cm in thickness with a luminal diameter of 1.0 cm and, a strip of mostly muscularis, infiltrated with blue suture material that measures 6.5 x 0.7 x 0.2 cm.

Representative sections of colon

4A ring of mucosa in toto, en face

4B muscularis

Quick Section Diagnosis

1. Proximal stomach and distal esophagus

-Esophageal margin, EIT, QS1B, 1C: Negative for malignancy

-Stomach margin, representative sections 1A and 1D (closest in 1A): Negative for malignancy

*Path TSS dx discrepancy form, TCGA
tumor is stomach adenocarcinoma, tubular
type*

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Intestinal NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Tubular	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Initial pathology report focused on all of the tissue. The CQCF refers to assessment of the specific block/ tissue sent to TCGA.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 0ed8af6b-98d6-4906-a3ec-b58aea4eb582 (TCGA-KB-A93H.6F6F9A10-864C-4611-A12E-FE08139FDD37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).